Somatic mutation profile of tumor specimen TCGA-EC-A24G-01A (aliquot TCGA-EC-A24G-01A-11D-A16D-09) from TCGA case TCGA-EC-A24G, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 57.1 years (20,857 days).
Specimen TCGA-EC-A24G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e692923f-8073-4d3f-aa2f-35aa648edd36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EC-A24G-10A (Blood Derived Normal), aliquot TCGA-EC-A24G-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dca24b4a-57a6-4a6a-bab8-e187d2658b30

The open-access MAF lists 1,274 somatic variants for this specimen: 924 protein-altering or splice-affecting, 325 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 789, Silent 325, Nonsense Mutation 59, Frame Shift Del 40, Splice Site 17, Intron 15, Frame Shift Ins 9, Splice Region 7, RNA 7, Nonstop Mutation 3, 5'Flank 2, 3'Flank 1.

Variants (750 of 1,274; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs61749409, CM990025, COSV100933342; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGL | c.3911del p.N1304Ifs*10 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ASPA | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.661); catalogued as rs770706390, CM001610, COSV53981194; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP8B1 | c.614del p.N205Mfs*33 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- BEST1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs281865239, CM003486, COSV57120998; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CASR | c.1378-6154G>A | Intron (SNP) | VAF 16/42 reads (38%) | catalogued as rs193922423, CM076074, COSV99949608; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNNM4 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs1455470131, CM136859, COSV100998630; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, varscan2
- FA2H | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372350326; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.832C>T p.R278* (on ENST00000281708 / NM_001349798.2; = p.R198* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | hotspot (GDC flag); catalogued as COSV55891638; called by muse, varscan2
- GTPBP2 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as rs1007812513, COSV100200223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSPG2 | c.1219dup p.Q407Pfs*62 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs763945561; ClinVar: likely pathogenic; called by mutect2, varscan2
- INSR | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs121913150, CM920379, COSV100253840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEGF10 | c.2104+1G>A p.X702_splice | Splice Site (SNP) | VAF 23/96 reads (24%) | catalogued as rs1298663120, COSV57255045, COSV99175528; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-1G>T p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 18/52 reads (35%) | hotspot (GDC flag); catalogued as COSV57125628, COSV57128950, COSV99163201; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 29/85 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121918468, CM043335, CM096577, COSV100692090, COSV61005148; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RALA | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1554297905, COSV50049211; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.4255C>T p.Q1419* | Nonsense Mutation (SNP) | VAF 25/94 reads (27%) | catalogued as rs45437193, CD010687, CM991212, COSV99239307; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AAK1 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs746642455, COSV101276047; called by muse, mutect2, varscan2
- ABCA2 | c.3263C>T p.T1088M (on ENST00000614293; = p.T1058M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs376153765, COSV55807883; called by muse, mutect2, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCA9 | c.2510G>A p.S837N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV100383650; called by muse, mutect2, varscan2
- ABCB6 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as rs147046586; called by muse, mutect2, varscan2
- AC109583.1 | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100168010; called by muse, mutect2, varscan2
- ACACB | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs780689830, COSV58141313; called by muse, mutect2, varscan2
- ACAD10 | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs1251428097, COSV58158694; called by muse, mutect2, varscan2
- ACHE | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV99574697; called by muse, mutect2, varscan2
- ACOX1 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs748619167, COSV99504102; called by muse, mutect2, varscan2
- ACTN2 | c.1267A>C p.I423L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100857113; called by muse, mutect2, varscan2
- ADAM19 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as rs773390573, COSV99978817; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65899174; called by muse, mutect2, varscan2
- ADAP1 | c.130T>G p.C44G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763494; called by muse, mutect2, varscan2
- ADGRB2 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99927139; called by muse, mutect2, varscan2
- ADGRF3 | c.943G>A p.E315K (on ENST00000311519 / NM_001145168.1; = p.E116K on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.087); catalogued as rs777458927, COSV61050902, COSV61054477; called by muse, mutect2, varscan2
- ADGRF5 | c.736A>G p.K246E | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV99346658; called by muse, mutect2, varscan2
- ADGRG6 | c.2092A>G p.I698V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs772801371, COSV99749324; called by muse, mutect2, varscan2
- ADNP | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV100823904; called by muse, mutect2, varscan2
- ADSS1 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780224589, COSV100272526; called by muse, mutect2, varscan2
- AFP | c.1333T>C p.S445P | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs567239570, COSV99890486; called by muse, mutect2, varscan2
- AGMAT | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs373540469; called by mutect2, varscan2
- AHCTF1 | c.558G>T p.W186C (on ENST00000366508; = p.W160C on NM_015446.5) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100404616; called by muse, mutect2, varscan2
- AKAP14 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1162600810, COSV100538443; called by muse, mutect2, varscan2
- AKAP14 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100538446, COSV57630191; called by muse, mutect2, varscan2
- ALDH16A1 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV99513310; called by muse, mutect2, varscan2
- ALOX12B | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs374296227; called by muse, mutect2, varscan2
- ALPK2 | c.4670C>T p.T1557M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs767681153, COSV100864939; called by muse, mutect2
- AMELX | c.419T>C p.M140T | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV100499485; called by muse, mutect2, varscan2
- AMHR2 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 9/14 reads (64%) | catalogued as rs114182001, CM128287, COSV57686933; called by muse, mutect2, varscan2
- ANAPC2 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); catalogued as rs775846010, COSV100119093; called by muse, mutect2, varscan2
- ANGPTL7 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs901100424, COSV100816801; called by muse, mutect2, varscan2
- ANK2 | c.3796+2T>C p.X1266_splice | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as rs1563865182, COSV100004787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD11 | c.7172G>A p.R2391H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1430920673, COSV99970957; called by muse, mutect2, varscan2
- ANKRD13B | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs562706819, COSV101198970; called by muse, mutect2, varscan2
- ANKRD26 | c.2258T>A p.I753N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1446588591, COSV101063496; called by muse, mutect2, varscan2
- ANKS3 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761486110, COSV100423253; called by muse, mutect2, varscan2
- AP3M2 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV99442028; called by muse, mutect2, varscan2
- APEX2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141646629, COSV100895225; called by muse, varscan2
- APP | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as rs199521746, COSV61001832; called by muse, mutect2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 21/100 reads (21%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP3 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV99955754; called by muse, mutect2, varscan2
- AQP7 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs373501318; called by muse, mutect2, varscan2
- ARAP3 | c.3136G>A p.A1046T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs1470815982, COSV99500437; called by muse, mutect2
- ARFGEF1 | c.5207G>A p.R1736Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs1261248319, COSV99142593; called by muse, mutect2, varscan2
- ARHGAP31 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748347343, COSV51798990; called by muse, mutect2, varscan2
- ARHGAP31 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as rs1205008776, COSV51792683; called by muse, mutect2, varscan2
- ARHGAP32 | c.3863C>T p.T1288I (on ENST00000310343 / NM_001378025.1; = p.T939I on NM_014715.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV100089756; called by muse, mutect2, varscan2
- ARHGAP33 | c.1532G>A p.S511N | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.988); catalogued as COSV99140605; called by muse, mutect2
- ARHGEF26 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV100726712; called by muse, mutect2, varscan2
- ARHGEF7 | c.1399C>T p.R467W (on ENST00000375741 / NM_001113511.2; = p.R289W on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs756849158, COSV54542291; called by muse, mutect2, varscan2
- ARID1A | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.211); catalogued as rs754046530, COSV61389078; called by muse, mutect2, varscan2
- ARMC4 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs181484327, COSV100536459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARPC2 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV99826934; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs761154268; called by mutect2, varscan2
- ASMTL | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs371220130, COSV101188029, COSV67243316; called by muse, mutect2, varscan2
- ASMTL | c.1378+2T>C p.X460_splice | Splice Site (SNP) | VAF 51/138 reads (37%) | catalogued as rs781053210, COSV101188031; called by muse, mutect2, varscan2
- ASMTL | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as rs751778300, COSV67245140; called by muse, mutect2, varscan2
- ASPSCR1 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs774394455, COSV100145083; called by muse, mutect2, varscan2
- ASTN2 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs1252370323, COSV57757897; called by muse, varscan2
- ASXL1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs376089258, COSV100041765; called by muse, mutect2, varscan2
- ASXL3 | c.3954G>T p.M1318I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV99327093; called by muse, mutect2, varscan2
- ATAD3A | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1167820219, COSV100186713; called by muse, mutect2, varscan2
- ATF2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV99909100; called by muse, mutect2, varscan2
- ATL1 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs985551666, COSV100613363; called by muse, mutect2, varscan2
- ATM | c.8708C>T p.P2903L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99592484; called by muse, mutect2, varscan2
- ATP1A2 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.387); catalogued as rs745824475, COSV100768235; called by muse, mutect2, varscan2
- ATP4A | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99383215; called by muse, mutect2, varscan2
- ATP6V0A1 | c.88G>T p.G30* | Nonsense Mutation (SNP) | VAF 49/153 reads (32%) | catalogued as COSV99231781; called by muse, mutect2, varscan2
- ATPSCKMT | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV99726012; called by muse, mutect2, varscan2
- ATXN2 | c.1631G>T p.R544I (on ENST00000550104; = p.R384I on NM_002973.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101112927; called by muse, mutect2, varscan2
- AURKB | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs879004728, COSV100298953; called by muse, mutect2
- AWAT2 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV99339823; called by muse, mutect2, varscan2
- B3GAT2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1251670929, COSV57771055; called by muse, mutect2, varscan2
- B3GNT3 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs142889952; called by muse, mutect2, varscan2
- B3GNT6 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62828372; called by muse, mutect2, varscan2
- B4GALNT4 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs376906010; called by muse, mutect2, varscan2
- B4GALT3 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs367870203, COSV60527194; called by muse, mutect2, varscan2
- BCAM | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747779314, COSV99539077; called by muse, mutect2, varscan2
- BCDIN3D | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777009576, COSV100445598; called by muse, mutect2, varscan2
- BCL11B | c.2447G>A p.R816Q (on ENST00000357195 / NM_001282237.2; = p.R745Q on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100596030, COSV61740350; called by muse, mutect2
- BHLHE22 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58863271; called by muse, mutect2, varscan2
- BIN1 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs756882994, COSV99388125; called by muse, mutect2, varscan2
- BNIP3L | c.424T>C p.S142P | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); catalogued as COSV101020149; called by muse, mutect2, varscan2
- BRAT1 | c.1616G>A p.C539Y | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs762435787, COSV100500754; called by muse, mutect2, varscan2
- BRDT | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs376776587; called by muse, mutect2, varscan2
- BSDC1 | c.397T>C p.C133R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100345228; called by muse, mutect2, varscan2
- BSN | c.10480C>T p.R3494* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as rs377087363; called by muse, mutect2, varscan2
- BTBD2 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.06); catalogued as COSV99725012; called by muse, mutect2, varscan2
- BVES | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100115192; called by muse, mutect2, varscan2
- C16orf46 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755731515, COSV55150813; called by muse, mutect2, varscan2
- C16orf71 | c.568T>C p.S190P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100173171; called by muse, mutect2, varscan2
- C19orf54 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as rs549826596, COSV99649149; called by muse, mutect2, varscan2
- C2orf16 | c.2059T>C p.S687P | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1313871750, COSV100821134; called by muse, mutect2, varscan2
- C5orf22 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100323710; called by muse, mutect2, varscan2
- C6 | c.631A>G p.N211D | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV99668011; called by muse, mutect2, varscan2
- CACNA1E | c.4925G>A p.R1642Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.274); catalogued as rs1381608974, COSV100705568, COSV62381870; called by muse, mutect2, varscan2
- CACNA1F | c.4027G>A p.V1343I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs151203138, COSV59904563; called by muse, mutect2, varscan2
- CAD | c.3775G>T p.V1259L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV53023575, COSV99256064; called by muse, mutect2, varscan2
- CALCR | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100810919; called by muse, mutect2, varscan2
- CALHM1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.738); catalogued as rs374702244; called by muse, mutect2, varscan2
- CAMKK1 | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1395835406, COSV99340666; called by muse, mutect2, varscan2
- CATSPER2 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV100391073; called by muse, mutect2, varscan2
- CBLB | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99914661; called by muse, mutect2
- CBLC | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs1188155125, COSV99542369; called by muse, mutect2, varscan2
- CCDC102A | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs369291975; called by muse, mutect2, varscan2
- CCDC112 | c.1031A>G p.K344R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV101100555; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC80 | c.2830T>C p.Y944H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99245446; called by muse, mutect2, varscan2
- CCDC88B | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.745); catalogued as COSV100106086; called by muse, mutect2, varscan2
- CCHCR1 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as rs570019609, COSV99456391; called by muse, varscan2
- CCHCR1 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs751269045, COSV99456394; called by muse, varscan2
- CCKBR | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224436970, COSV58099220; called by muse, mutect2, varscan2
- CCNA1 | c.108+1G>A p.X36_splice | Splice Site (SNP) | VAF 15/69 reads (22%) | catalogued as rs756585634, COSV99715028; called by muse, mutect2, varscan2
- CCNP | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99695959; called by muse, mutect2, varscan2
- CCP110 | c.2605G>A p.G869S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.308); catalogued as rs777831149, COSV101195363; called by muse, mutect2, varscan2
- CCSER1 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748961219, COSV61443763; called by muse, mutect2, varscan2
- CD19 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV100218314; called by muse, mutect2, varscan2
- CD1B | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as rs753768677, COSV100939317, COSV63804179; called by muse, mutect2, varscan2
- CD40 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1383835191, COSV100953890; called by muse, mutect2, varscan2
- CDH13 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as rs1424536545, COSV99232506; called by muse, mutect2, varscan2
- CDH20 | c.1949A>G p.Y650C | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs767247001, COSV99406778; called by muse, mutect2, varscan2
- CDH24 | c.771del p.K258Sfs*36 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs753422808; called by mutect2, pindel, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 19/43 reads (44%) | catalogued as rs759091263; called by mutect2, varscan2
- CELA2B | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs535515233, COSV62747409; called by muse, mutect2, varscan2
- CELSR3 | c.8773C>T p.R2925W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs951042380, COSV99375418; called by muse, mutect2, varscan2
- CELSR3 | c.8174G>A p.R2725H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as rs778736769, COSV50841570; called by muse, mutect2, varscan2
- CEP135 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs377176971; called by muse, mutect2, varscan2
- CEP192 | c.4209G>A p.W1403* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV100382403; called by muse, mutect2, varscan2
- CEP76 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.783); catalogued as COSV100043071; called by muse, mutect2, varscan2
- CER1 | c.401G>A p.W134* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as rs781098087, COSV101097946; called by muse, mutect2, varscan2
- CGB2 | c.432del p.S145Afs*? | Frame Shift Del (DEL) | VAF 49/157 reads (31%) | catalogued as rs780705864, COSV56821141; called by mutect2, pindel, varscan2
- CGB7 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs752113515, COSV100655123; called by mutect2, varscan2
- CGN | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs371835042; called by muse, mutect2, varscan2
- CHD5 | c.3694G>A p.A1232T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.131); catalogued as rs558552874; called by muse, mutect2, varscan2
- CHM | c.1634G>T p.R545I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs767228121, COSV100753720; called by muse, mutect2, varscan2
- CHMP4B | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775903669, COSV54136242, COSV99460089; called by muse, mutect2, varscan2
- CHN1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs777005219, COSV101303571; called by muse, mutect2, varscan2
- CHPF | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559473455, COSV60535280; called by muse, mutect2, varscan2
- CIC | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50549905, COSV50559779; called by muse, mutect2, varscan2
- CLPTM1L | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs774759213, COSV100307418; called by muse, mutect2, varscan2
- CLSPN | c.1947G>T p.K649N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99230319; called by muse, mutect2, varscan2
- CNGB3 | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs772444831, COSV60685260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.2710G>A p.G904S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV101444385; called by muse, mutect2, varscan2
- COA6 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV64016762; called by muse, mutect2
- COL4A4 | c.2491G>A p.G831S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100307997; called by muse, mutect2, varscan2
- COL6A6 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as rs758024809, COSV100651100; called by muse, mutect2, varscan2
- COL9A1 | c.830C>A p.P277H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV100295916, COSV57886919; called by muse, mutect2, varscan2
- CPEB2 | c.2014G>A p.G672R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52592729; called by muse, mutect2, varscan2
- CPO | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1008986901, COSV99786723; called by muse, mutect2, varscan2
- CPSF2 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100103051; called by muse, mutect2, varscan2
- CREBBP | c.7319A>T p.E2440V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99272906; called by muse, mutect2, varscan2
- CROCC | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV100978405; called by muse, mutect2, varscan2
- CRYGN | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100484844; called by muse, mutect2, varscan2
- CSF1R | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs763119382, COSV99036330; called by muse, mutect2, varscan2
- CSMD2 | c.4006G>A p.G1336R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs368584183; called by muse, mutect2, varscan2
- CTIF | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1464961999, COSV99838673; called by muse, mutect2, varscan2
- CTR9 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1245642519, COSV100797380; called by muse, mutect2
- CTTNBP2NL | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs370336631; called by muse, mutect2, varscan2
- CUL1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV57388811; called by muse, mutect2, varscan2
- CUX2 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV55640580; called by muse, mutect2, varscan2
- CYFIP2 | c.1318T>C p.Y440H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100558008; called by muse, mutect2, varscan2
- CYP11B2 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311444460, COSV100011482; ClinVar: uncertain significance; called by muse, varscan2
- CYP4F11 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs142657300; called by muse, mutect2, varscan2
- CYP4V2 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776616377, CM119423, COSV101115009; called by muse, mutect2
- DAGLA | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs747581853, COSV99944823; called by muse, mutect2, varscan2
- DAGLB | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.303); catalogued as rs1318401501, COSV99766280; called by muse, mutect2, varscan2
- DBNL | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV101289347; called by muse, mutect2, varscan2
- DCAF12L1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100948492, COSV99058403; called by muse, mutect2, varscan2
- DCAF5 | c.1117G>C p.D373H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100432904, COSV58460606; called by muse, mutect2, varscan2
- DCC | c.2800A>G p.T934A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as COSV100503782; called by muse, mutect2, varscan2
- DCHS1 | c.8015G>A p.R2672Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs752415774, COSV54995962; called by muse, mutect2, varscan2
- DCP1A | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs781893027, COSV99588305; called by muse, mutect2, varscan2
- DDIAS | c.2858T>G p.V953G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as COSV100231510; called by muse, mutect2, varscan2
- DDX4 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.382); catalogued as COSV100737863; called by muse, mutect2
- DDX42 | c.286T>C p.S96P | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100835129; called by muse, mutect2
- DDX55 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769029985, COSV99434920; called by muse, mutect2, varscan2
- DDX59 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.736); catalogued as rs759640859, COSV100494567; called by muse, mutect2, varscan2
- DEFB113 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201564508; called by muse, mutect2, varscan2
- DHCR7 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1157310044, COSV100832207; called by muse, mutect2, varscan2
- DHRS13 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs1234847029, COSV100242188; called by muse, mutect2, varscan2
- DHX33 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs150739714; called by muse, mutect2, varscan2
- DHX58 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99288608; called by muse, mutect2, varscan2
- DIP2A | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); catalogued as COSV100595400; called by muse, mutect2, varscan2
- DISP3 | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV53838931; called by muse, mutect2, varscan2
- DLG5 | c.4742G>A p.R1581H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.711); catalogued as rs953419715, COSV64946817; called by muse, mutect2, varscan2
- DLGAP3 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99333333; called by muse, mutect2, varscan2
- DLGAP4 | c.525G>T p.E175D | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100211704; called by muse, mutect2, varscan2
- DLX2 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99308717; called by muse, mutect2, varscan2
- DMRTA1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs144441630; called by muse, mutect2, varscan2
- DNAH1 | c.5096C>T p.A1699V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs954066157, COSV101327078; called by muse, mutect2, varscan2
- DNAH11 | c.6551T>C p.L2184S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100181452; called by muse, mutect2, varscan2
- DNAH17 | c.12970G>A p.G4324S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779260124, COSV53145151; called by muse, mutect2, varscan2
- DNAH17 | c.9718G>A p.G3240S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs750715276, COSV67750814; called by muse, mutect2, varscan2
- DNAH17 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs745983884, COSV101103854; called by muse, mutect2, varscan2
- DNAH5 | c.7475C>T p.A2492V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs529080443, COSV99455587; ClinVar: uncertain significance; called by muse, varscan2
- DNAH7 | c.4712C>T p.A1571V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100418188; called by muse, mutect2, varscan2
- DNAI4 | c.2254G>A p.D752N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375105342; called by muse, mutect2, varscan2
- DNAJC1 | c.673T>C p.C225R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs771735296, COSV100978059; called by muse, mutect2, varscan2
- DNAJC3 | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV100953350; called by muse, mutect2, varscan2
- DOCK1 | c.4057C>T p.R1353W | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1293651177, COSV54763963; called by muse, mutect2, varscan2
- DOCK6 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99626990; called by muse, mutect2, varscan2
- DOCK7 | c.5724G>T p.K1908N (on ENST00000635253 / NM_001367561.1; = p.K1877N on NM_033407.3) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99226429; called by muse, mutect2, varscan2
- DPF3 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369823716; called by muse, mutect2, varscan2
- DPP9 | c.530C>T p.P177L (on ENST00000598800; = p.P206L on NM_139159.5) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779459195, COSV99506611; called by muse, mutect2, varscan2
- DPRX | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1009518882, COSV100934143; called by muse, mutect2, varscan2
- DPYSL2 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs1283012689, COSV100234348; called by muse, mutect2, varscan2
- DST | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.082); catalogued as COSV100424827; called by muse, mutect2, varscan2
- DYNC2H1 | c.10265T>G p.L3422R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100520029; called by muse, mutect2, varscan2
- DYNC2H1 | c.12866G>A p.G4289E | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV100520030; called by muse, mutect2, varscan2
- DYSF | c.1880C>T p.T627I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs1451872696, COSV99251200; called by muse, mutect2, varscan2
- EEF2 | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100501063; called by muse, mutect2, varscan2
- EIF4E2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs572423747, COSV99299384; called by muse, mutect2, varscan2
- EIF4G1 | c.1003G>A p.V335I (on ENST00000346169 / NM_198241.3; = p.V139I on NM_004953.5) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100072427; called by muse, mutect2, varscan2
- EIF4G3 | c.1807G>A p.G603R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV99945990; called by muse, mutect2, varscan2
- EIF4G3 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765519866, COSV99946003; called by muse, mutect2, varscan2
- ELK3 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.978); catalogued as rs377210503; called by muse, mutect2, varscan2
- ELOA3C | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV55303219; called by muse, mutect2
- ELP3 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99834275; called by muse, mutect2, varscan2
- ELP3 | c.1144A>G p.N382D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs746560423, COSV99834280; called by muse, mutect2, varscan2
- ELP6 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs931047050, COSV56132034; called by muse, mutect2, varscan2
- EMILIN1 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV53153673, COSV99566651; called by muse, mutect2, varscan2
- EML3 | c.210del p.G71Dfs*11 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | catalogued as COSV53882579; called by mutect2, varscan2
- ENG | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as COSV100785365; called by muse, mutect2, varscan2
- ENPP2 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99309628; called by muse, mutect2, varscan2
- ENPP3 | c.1733C>A p.P578H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100718263; called by muse, mutect2, varscan2
- EP400 | c.8489C>T p.T2830M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs747669519, COSV100202573; called by muse, mutect2, varscan2
- EPPK1 | c.1550A>G p.E517G | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV101599987; called by muse, mutect2, varscan2
- EPS15L1 | c.461T>G p.L154R | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99933896; called by muse, mutect2, varscan2
- ERC2 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779075464, COSV99881393; called by muse, mutect2, varscan2
- ERCC4 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as COSV100319172; called by muse, mutect2, varscan2
- ESYT3 | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538046539, COSV67440793; called by muse, mutect2, varscan2
- ETS1 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs760141484, COSV60092490; called by muse, mutect2, varscan2
- ETV5 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100112642; called by muse, mutect2, varscan2
- ETV7 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.44); catalogued as rs200738569, COSV100339388; called by muse, mutect2, varscan2
- EVC | c.1652del p.P551Rfs*7 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs1312383000; called by mutect2, pindel, varscan2
- EXPH5 | c.5303G>A p.S1768N | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.038); catalogued as COSV56198382, COSV99762411; called by muse, mutect2, varscan2
- FAIM | c.195A>G p.I65M | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100624051; called by muse, mutect2, varscan2
- FAM135B | c.2408G>A p.S803N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV52716667, COSV52755853; called by muse, mutect2, varscan2
- FAM153A | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.402); catalogued as COSV100647139; called by muse, mutect2, varscan2
- FAM161A | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100281587; called by muse, mutect2, varscan2
- FAM222A | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV100734645; called by muse, mutect2, varscan2
- FAM83B | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs753449193, COSV60919807; called by muse, mutect2, varscan2
- FAM91A1 | c.1646T>C p.L549P | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100593862; called by muse, mutect2, varscan2
- FASN | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.187); catalogued as rs1255742032, COSV100148467; called by muse, mutect2, varscan2
- FAT1 | c.9460G>A p.A3154T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs759492838, COSV101499530; called by muse, mutect2, varscan2
- FAT1 | c.6199G>A p.V2067M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs980333559, COSV71671770; called by muse, mutect2, varscan2
- FAT2 | c.11180G>A p.C3727Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99944509; called by muse, mutect2, varscan2
- FBXL13 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as rs746621370, COSV100502288; called by muse, mutect2, varscan2
- FCF1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs142533630; called by muse, mutect2, varscan2
- FCGBP | c.6655G>A p.A2219T | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.137); catalogued as COSV99664632; called by muse, mutect2, varscan2
- FCRL3 | c.414A>C p.K138N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.159); catalogued as COSV100943632; called by muse, mutect2, varscan2
- FEZ1 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs939724094, COSV99631347; called by muse, mutect2, varscan2
- FGF23 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.478); catalogued as rs934951717, COSV99426794; called by muse, mutect2, varscan2
- FGFBP1 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99469218; called by muse, mutect2, varscan2
- FGFR1OP2 | c.161A>T p.N54I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV99987089; called by muse, mutect2, varscan2
- FGFR4 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs145751771, COSV99451147; called by muse, mutect2, varscan2
- FKBP14 | c.29T>C p.L10S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV99322411; called by muse, mutect2, varscan2
- FLG | c.6077A>G p.Q2026R | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV100912439; called by muse, mutect2, varscan2
- FLNA | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.163); catalogued as rs782776511, COSV100775395; ClinVar: likely benign; called by muse, varscan2
- FLNA | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs1399359867, COSV100775399; called by muse, varscan2
- FMOD | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs150991415; called by muse, mutect2, varscan2
- FOXD4L3 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.6); catalogued as COSV61551680; called by muse, varscan2
- FPR2 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100389499; called by muse, mutect2, varscan2
- FREM2 | c.5366T>C p.V1789A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV99751547; called by muse, mutect2, varscan2
- FRMPD1 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760852978, COSV100899686; called by muse, mutect2, varscan2
- FRMPD4 | c.1456G>A p.V486M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs757368234, COSV101044343; called by muse, mutect2, varscan2
- FYB2 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100599865; called by muse, mutect2
- FZD1 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1563008272, COSV55312341; called by muse, mutect2, varscan2
- FZD6 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100708526; called by muse, mutect2, varscan2
- GABBR1 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV100590197; called by muse, mutect2, varscan2
- GALE | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs756590751, COSV99354151; called by muse, mutect2, varscan2
- GALK2 | c.266+1G>A p.X89_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | catalogued as rs1196042284, COSV100509350; called by muse, mutect2, varscan2
- GALR1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs770801123, COSV100232148; called by muse, mutect2
- GALT | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as rs777023967, CM012761, COSV66592580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAS2L3 | c.1696G>A p.V566M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.233); catalogued as COSV99903244; called by muse, mutect2, varscan2
- GBF1 | c.5501C>T p.A1834V (on ENST00000369983 / NM_001377137.1; = p.A1833V on NM_004193.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs770517190, COSV64144592; called by mutect2, varscan2
- GCA | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99280716; called by muse, mutect2
- GCH1 | c.159G>C p.W53C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as CD067172, COSV99582183; called by muse, mutect2, varscan2
- GCN1 | c.7579A>G p.S2527G | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.195); catalogued as COSV100326247; called by muse, mutect2, varscan2
- GFPT1 | c.2069G>A p.R690Q (on ENST00000357308 / NM_001244710.2; = p.R672Q on NM_002056.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100623036; called by mutect2, varscan2
- GLP1R | c.1091A>G p.E364G | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100952785; called by muse, mutect2, varscan2
- GLUD2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1242646247, COSV100047176; called by muse, mutect2, varscan2
- GNL2 | c.2043A>G p.E681= | Splice Region (SNP) | VAF 26/109 reads (24%) | catalogued as COSV99953793; called by muse, mutect2, varscan2
- GP1BA | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs1436997235, COSV56698851; called by muse, mutect2, varscan2
- GPC2 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as rs1279142519, COSV52784720; called by muse, mutect2, varscan2
- GPLD1 | c.820A>G p.S274G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as rs1377480017, COSV100015651; called by muse, mutect2, varscan2
- GPM6A | c.231-1G>T p.X77_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99706072; called by muse, mutect2, varscan2
- GRAMD1B | c.1928T>C p.M643T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100455377; called by muse, mutect2, varscan2
- GREB1 | c.4348C>T p.R1450C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771295305, COSV99304048; called by muse, mutect2, varscan2
- GRIA1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777000021, COSV53590416; called by muse, mutect2, varscan2
- GRIN2A | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV58050893; called by muse, mutect2, varscan2
- GRM3 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100863019; called by muse, mutect2, varscan2
- GRXCR2 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV100940063, COSV65061508; called by muse, mutect2, varscan2
- GTF3C1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs771961160, COSV100649825; called by muse, mutect2, varscan2
- GUSB | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs780835314, COSV100512811; called by muse, mutect2, varscan2
- GYG2 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58550879; called by muse, mutect2, varscan2
- H2BC4 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV58416238; called by muse, mutect2, varscan2
- HADHA | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373966336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCFC1 | c.4780G>A p.E1594K | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); catalogued as rs1466759880, COSV100130187; called by muse, mutect2, varscan2
- HDAC10 | c.1799T>C p.L600P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99352741; called by muse, mutect2, varscan2
- HDAC11 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs749223823, COSV55472255, COSV99849809; called by muse, mutect2, varscan2
- HDAC4 | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61860719; called by muse, mutect2, varscan2
- HEATR1 | c.4570C>T p.L1524F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100857837; called by muse, mutect2, varscan2
- HELZ2 | c.3779G>A p.R1260Q (on ENST00000467148 / NM_001037335.2; = p.R691Q on NM_033405.3) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs1031390031; called by muse, mutect2
- HEPH | c.845T>G p.L282R (on ENST00000343002; = p.L15R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100295979; called by muse, mutect2, varscan2
- HERC6 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1409834577, COSV99910713; called by muse, mutect2, varscan2
- HIBCH | c.442G>C p.V148L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as COSV100676334; called by muse, mutect2, varscan2
- HIF3A | c.1067C>T p.T356M (on ENST00000377670 / NM_152795.4; = p.T287M on NM_022462.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs569551991, COSV52196457; called by muse, mutect2, varscan2
- HM13 | c.809-1G>A p.X270_splice | Splice Site (SNP) | VAF 29/141 reads (21%) | catalogued as COSV100159865, COSV59439437; called by muse, mutect2, varscan2
- HMGCR | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs764763607, COSV55316018; called by muse, mutect2, varscan2
- HNRNPH1 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100271046; called by muse, mutect2, varscan2
- HOOK3 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs777110373, COSV56879587; called by muse, mutect2, varscan2
- HOXC4 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.186); catalogued as COSV100324454; called by muse, mutect2, varscan2
- HPD | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774495352, COSV56641675, COSV56643127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HRNR | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150593074, COSV64258973; called by muse, mutect2, varscan2
- HS6ST2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs1212807870; called by muse, mutect2
- HSD17B12 | c.36C>G p.Y12* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99551190; called by muse, mutect2, varscan2
- HTR1A | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100109341; called by muse, mutect2
- HUWE1 | c.8257G>A p.A2753T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99474883; called by muse, mutect2, varscan2
- HYDIN | c.6737C>T p.A2246V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV99994022; called by muse, mutect2, varscan2
- HYOU1 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as rs781850918, COSV101345706; called by muse, mutect2, varscan2
- IARS2 | c.1613A>G p.K538R | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as rs779425903, COSV100228719; called by muse, mutect2, varscan2
- IBTK | c.2936A>G p.K979R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1360022180, COSV100091659; called by muse, mutect2, varscan2
- IBTK | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV100091661; called by muse, mutect2, varscan2
- IFNA5 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV52386838, COSV52387284; called by muse, mutect2, varscan2
- IFNA8 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV101206950; called by muse, mutect2
- IGF1R | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.048); catalogued as rs987303175, COSV99163595; called by muse, mutect2, varscan2
- IGF2 | c.452C>T p.S151L (on ENST00000434045 / NM_001127598.3; = p.S95L on NM_000612.6) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1457247306, COSV100324315; called by muse, mutect2, varscan2
- IGHA1 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372490697; called by muse, mutect2, varscan2
- IGSF3 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369252833, COSV100605194; called by muse, mutect2, varscan2
- IKBKB | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV60598385; called by muse, mutect2, varscan2
- IKZF3 | c.823A>G p.I275V | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99500271; called by muse, mutect2, varscan2
- IL12RB1 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374771268; called by muse, mutect2, varscan2
- ILF3 | c.2443C>T p.R815* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV99140469; called by muse, mutect2, varscan2
- INCA1 | c.709T>C p.*237Qext*? (on ENST00000574617 / NM_001167986.1; = p.*222Qext*? on NM_213726.2) | Nonstop Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100742080; called by muse, mutect2, varscan2
- INPP5D | c.2785G>A p.V929M (on ENST00000445964 / NM_001017915.3; = p.V928M on NM_005541.5) | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs760843259, COSV64038901; called by muse, mutect2
- INPP5K | c.552C>T p.H184= | Splice Region (SNP) | VAF 23/79 reads (29%) | catalogued as rs749984324, COSV100233972; called by muse, mutect2, varscan2
- INTS1 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV101247560; called by muse, mutect2, varscan2
- IQCH | c.2726G>A p.S909N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs778029271, COSV100246452; called by muse, mutect2, varscan2
- IQGAP3 | c.3305C>T p.P1102L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs780842801, COSV100752144; called by muse, mutect2, varscan2
- IQSEC1 | c.2756G>A p.R919H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324202560, COSV99832005; called by muse, mutect2, varscan2
- IQSEC2 | c.3041A>T p.K1014M (on ENST00000642864 / NM_001111125.3; = p.K809M on NM_015075.2) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100945141; called by muse, mutect2, varscan2
- ISCU | c.398C>T p.P133L (on ENST00000311893 / NM_213595.4; = p.P108L on NM_014301.4) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57810177; called by muse, mutect2, varscan2
- ISG15 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as rs148041041, COSV65106509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGAL | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs764357270, COSV63322087; called by muse, mutect2, varscan2
- ITGB4 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV99565049; called by muse, mutect2, varscan2
- ITGB4 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs759740979, COSV52330815; called by muse, mutect2, varscan2
- ITGB5 | c.1805G>A p.C602Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99951170; called by muse, mutect2, varscan2
- ITIH2 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV100623484; called by muse, mutect2, varscan2
- ITIH3 | c.2585C>T p.T862M | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs762645645, COSV99820054; called by muse, mutect2
- ITM2A | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.719); catalogued as COSV64810846; called by muse, mutect2, varscan2
- ITPK1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777045448, COSV50894591; called by muse, mutect2, varscan2
- ITPKB | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs767184522, COSV55259300; called by muse, mutect2, varscan2
- ITPR2 | c.3839A>T p.N1280I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101190286; called by muse, mutect2, varscan2
- JAG1 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs756787187, COSV99653617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAK1 | c.3100T>C p.Y1034H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53811102, COSV99605795; called by muse, mutect2, varscan2
- JOSD2 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs141204557, COSV100976088; called by muse, varscan2
- JRKL | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745489757, COSV99567635; called by muse, mutect2, varscan2
- KANSL3 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100831277; called by muse, mutect2, varscan2
- KASH5 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs757572871, COSV71358558; called by muse, mutect2, varscan2
- KCNH7 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as rs750167052, COSV100038316; called by muse, mutect2, varscan2
- KCNQ3 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749712918, COSV66463567; called by muse, mutect2, varscan2
- KCNV2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); catalogued as rs1476130174, COSV101172642; called by muse, varscan2
- KCNV2 | c.1055T>G p.L352R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101172660; called by muse, mutect2, varscan2
- KCTD8 | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV100760247; called by muse, mutect2, varscan2
- KDM3B | c.3286A>G p.T1096A | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100070365; called by muse, mutect2, varscan2
- KDM4A | c.915+2T>C p.X305_splice | Splice Site (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100969716; called by muse, mutect2, varscan2
- KDM4D | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.141); catalogued as rs587708325, COSV100624396; called by muse, mutect2, varscan2
- KDM5C | c.4038G>A p.K1346= | Splice Region (SNP) | VAF 19/100 reads (19%) | catalogued as COSV100949584; called by muse, mutect2, varscan2
- KDM6B | c.3358G>A p.A1120T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1300689796, COSV99642321; called by muse, mutect2, varscan2
- KDM7A | c.2490G>T p.K830N | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV99135283; called by muse, mutect2, varscan2
- KIAA1549 | c.5755C>A p.Q1919K (on ENST00000422774 / NM_001164665.2; = p.Q1903K on NM_020910.3) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV99652354; called by muse, mutect2, varscan2
- KIAA1755 | c.3235G>T p.G1079C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV99642865; called by muse, mutect2, varscan2
- KIF13B | c.4630G>A p.V1544I | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV101342292; called by muse, mutect2
- KIF2C | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs766564343, COSV64763878; called by muse, mutect2, varscan2
- KLHDC1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs200431928, COSV63778506; called by muse, mutect2, varscan2
- KLHL25 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.494); catalogued as rs149329403; called by muse, mutect2, varscan2
- KLK12 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99142122; called by muse, mutect2
- KLK8 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99143861; called by muse, mutect2, varscan2
- KMT2D | c.13403G>A p.R4468Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1214747607, COSV56442076; called by muse, mutect2, varscan2
- KRT15 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV99563380; called by muse, mutect2
- KRT19 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs752847530, COSV99563382; called by muse, mutect2, varscan2
- KRT25 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100379772; called by muse, mutect2, varscan2
- KRT77 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100527326; called by muse, mutect2, varscan2
- LAMA1 | c.7876G>A p.G2626R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101058044; called by muse, mutect2, varscan2
- LAMB1 | c.4258G>A p.E1420K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs564358099, COSV55967593; called by muse, mutect2, varscan2
- LAMB1 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as rs1370434147, COSV55963202, COSV55969793; called by muse, mutect2, varscan2
- LAMB4 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs774051391, COSV99226109; called by muse, mutect2, varscan2
- LARP1B | c.2386T>C p.F796L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99219087; called by muse, mutect2, varscan2
- LARP4 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV53323532; called by muse, mutect2, varscan2
- LARP4B | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs148251856; called by muse, mutect2, varscan2
- LAS1L | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs756828005, COSV100408734; called by muse, mutect2, varscan2
- LENG1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs200559947; called by muse, mutect2, varscan2
- LIMK1 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs191821726, COSV60280954, COSV60283387; called by muse, mutect2, varscan2
- LIPE | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368445160; called by muse, mutect2, varscan2
- LLGL2 | c.2435T>G p.L812R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99390699; called by muse, mutect2, varscan2
- LMTK3 | c.3044C>T p.T1015M | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV54315230; called by muse, mutect2, varscan2
- LNPK | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99769955; called by muse, mutect2, varscan2
- LOXL2 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV56119785, COSV99743796; called by muse, mutect2, varscan2
- LOXL2 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs138663166; called by muse, mutect2, varscan2
- LPAR2 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99179685; called by muse, mutect2, varscan2
- LPIN1 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1368552319, COSV56766346; called by muse, mutect2, varscan2
- LPP | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs756437011, COSV57080914; called by muse, mutect2, varscan2
- LRBA | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV63962896; called by muse, mutect2, varscan2
- LRCH4 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs746804965, COSV56166431; called by muse, mutect2, varscan2
- LRFN1 | c.1076T>C p.I359T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV99953496; called by muse, mutect2, varscan2
- LRFN4 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV100540923; called by muse, mutect2, varscan2
- LRP12 | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99408498; called by muse, mutect2, varscan2
- LTBP2 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs770132775, COSV56209504; called by muse, mutect2, varscan2
- LTBP4 | c.2344G>A p.G782S (on ENST00000308370 / NM_001042544.1; = p.G745S on NM_003573.2) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1213024554, COSV99199799; called by muse, mutect2, varscan2
- LYRM1 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1247530649, COSV54644479; called by muse, mutect2, varscan2
- MAGI1 | c.4202G>A p.R1401Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV100443508; called by muse, mutect2, varscan2
- MAGIX | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1557097997, COSV100891949; called by muse, mutect2, varscan2
- MAGOHB | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs745448693, COSV100296360; called by muse, mutect2, varscan2
- MAIP1 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as rs115358893, COSV99705383; called by muse, mutect2, varscan2
- MAMDC2 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756987543, COSV101015667; called by muse, mutect2, varscan2
- MAMDC2 | c.1231T>C p.C411R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101015984; called by muse, mutect2, varscan2
- MAMDC4 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs139104706; called by muse, mutect2
- MAMLD1 | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); catalogued as rs782453177, CM152164, COSV99476705; called by muse, mutect2, varscan2
- MAN2A2 | c.3443G>A p.R1148H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs765464512, COSV100848069; called by muse, mutect2, varscan2
- MAN2C1 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.792); catalogued as rs1404037955, COSV99145960; called by muse, mutect2, varscan2
- MANEA | c.251A>G p.K84R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.232); catalogued as COSV100721711; called by muse, mutect2, varscan2
- MAP2K2 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs999810842, COSV53564414; ClinVar: uncertain significance; called by muse, mutect2
- MAP2K5 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV51622066; called by muse, mutect2, varscan2
- MAP3K12 | c.2554C>T p.R852W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as rs868492564, COSV99913708; called by muse, mutect2, varscan2
- MAP3K14 | c.1853T>A p.I618N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232063815, COSV100766592; called by muse, mutect2, varscan2
- MAP3K19 | c.3863C>A p.P1288H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100209484; called by muse, mutect2, varscan2
- MAP3K21 | c.2842G>A p.A948T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs769813222, COSV100786181; called by mutect2, varscan2
- MAST2 | c.2402T>C p.I801T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV100788933; called by mutect2, varscan2
- MATR3 | c.304C>A p.R102S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.972); catalogued as COSV100735355; called by muse, mutect2, varscan2
- MBD5 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV101290300; called by muse, mutect2, varscan2
- MBTPS1 | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as rs369203745; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM2 | c.2434C>T p.R812C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs766565920, COSV54032012; called by muse, mutect2, varscan2
- MEF2B | c.675C>T p.S225= | Splice Region (SNP) | VAF 6/19 reads (32%) | catalogued as rs150680281, COSV99365192; called by muse, mutect2, varscan2
- MEGF6 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.776); catalogued as rs1468233973, COSV53885731; called by muse, mutect2, varscan2
- MFSD1 | c.841T>G p.F281V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99964163; called by muse, mutect2
- MGAT4B | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs755592209, COSV52979927; called by muse, mutect2, varscan2
- MIGA2 | c.1391G>T p.S464I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99477959; called by muse, mutect2, varscan2
- MKNK1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1210270198, COSV100361585; called by muse, mutect2, varscan2
- MMP17 | c.968+1G>A p.X323_splice | Splice Site (SNP) | VAF 34/132 reads (26%) | catalogued as rs756600031, COSV100862000; called by muse, mutect2, varscan2
- MPEG1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs768506219, COSV99916062; called by muse, mutect2, varscan2
- MROH1 | c.4363C>T p.R1455W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1239194209; called by muse, mutect2, varscan2
- MRPL18 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99277985; called by muse, mutect2, varscan2
- MSGN1 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV55262594; called by muse, mutect2, varscan2
- MSH6 | c.3793G>T p.G1265* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99317200; called by muse, mutect2, varscan2
- MTHFR | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775245791, COSV100411646, COSV56743454; called by muse, mutect2, varscan2
- MTIF2 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774462033, COSV99703249; called by muse, mutect2, varscan2
- MTSS2 | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs760420108, COSV99852046; called by muse, mutect2, varscan2
- MUC5AC | c.14164G>A p.V4722M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs756204247, COSV100611440; called by muse, mutect2, varscan2
- MUC5B | c.8722G>A p.V2908I | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.035); catalogued as rs745678847, COSV71597420; called by muse, mutect2, varscan2
- MXRA5 | c.6371C>T p.A2124V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV99479856; called by muse, mutect2, varscan2
- MYLK4 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780121652, COSV51139360; called by muse, mutect2, varscan2
- MYO1C | c.2672G>A p.S891N (on ENST00000648651 / NM_001080779.2; = p.S856N on NM_033375.5) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100704610; called by muse, mutect2, varscan2
- MYO7B | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101268437; called by muse, mutect2, varscan2
- MYO9A | c.2833G>A p.V945I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100614647; called by muse, mutect2
- NAA40 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769477305, COSV100624253; called by muse, mutect2, varscan2
- NAA60 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100692875; called by muse, mutect2, varscan2
- NADK | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs780824098, COSV100411119; called by muse, mutect2, varscan2
- NAV1 | c.5047G>A p.V1683M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as COSV99819917; called by muse, mutect2, varscan2
- NBEA | c.6139C>A p.L2047I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100085089; called by muse, mutect2, varscan2
- NCAPD2 | c.2542C>T p.R848* | Nonsense Mutation (SNP) | VAF 29/105 reads (28%) | catalogued as rs139932236; called by muse, varscan2
- NCBP1 | c.932G>T p.R311I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100912717; called by muse, mutect2, varscan2
- NCOR1 | c.4137G>T p.E1379D | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV99252750; called by muse, mutect2
- NDUFV1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs773121558, COSV100295443; called by mutect2, varscan2
- NECTIN1 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757477808, COSV99872787; called by muse, mutect2, varscan2
- NEDD4L | c.2873G>A p.R958Q (on ENST00000400345 / NM_001144967.3; = p.R938Q on NM_015277.6) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs777624478, COSV56845561; called by muse, mutect2, varscan2
- NEFL | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.392); catalogued as rs1162304765, COSV55336147; called by muse, mutect2, varscan2
- NEFM | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV55330703; called by muse, mutect2, varscan2
- NEK6 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99413157; called by muse, mutect2, varscan2
- NELFA | c.1069G>T p.A357S (on ENST00000542778; = p.A346S on NM_005663.5) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV100374084; called by muse, mutect2, varscan2
- NETO1 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 31/109 reads (28%) | catalogued as COSV100199264; called by muse, mutect2, varscan2
- NEUROD1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs754458532, COSV54548773; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFATC1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.964); catalogued as rs769706337, COSV99502444; called by muse, mutect2, varscan2
- NFATC3 | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949395717, COSV100285889; called by muse, mutect2, varscan2
- NFE2L3 | c.1369T>C p.S457P | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99284111; called by muse, mutect2, varscan2
- NFIC | c.1331C>A p.P444H (on ENST00000443272 / NM_001245002.2; = p.P435H on NM_205843.3) | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100545714; called by muse, mutect2, varscan2
- NGDN | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1324385814, COSV101238944; called by muse, mutect2, varscan2
- NHS | c.4744C>T p.R1582C | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176455254, COSV66284316; called by muse, mutect2, varscan2
- NID1 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs542790055, COSV99938488; called by muse, mutect2, varscan2
- NLGN2 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs866866475, COSV100192929; called by muse, mutect2, varscan2
- NLGN4X | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.74); catalogued as rs780881503, COSV99324567; called by muse, mutect2, varscan2
- NLK | c.416A>C p.E139A | Missense Mutation (SNP) | VAF 93/280 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.803); catalogued as COSV101311436; called by muse, mutect2, varscan2
- NLRC3 | c.1243T>C p.F415L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100073647; called by muse, mutect2, varscan2
- NLRX1 | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99425067; called by muse, mutect2, varscan2
- NMNAT1 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs201994921, CM155281, COSV65882648; called by muse, mutect2, varscan2
- NOTCH2 | c.5024G>T p.R1675L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV56694494, COSV99867440; called by muse, mutect2, varscan2
- NPFFR2 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100441458; called by muse, mutect2, varscan2
- NR3C1 | c.1681A>C p.T561P | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99196902; called by muse, mutect2, varscan2
- NR3C1 | c.1247C>A p.P416Q | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.671); catalogued as COSV51545653; called by muse, mutect2, varscan2
- NRP1 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs924149280, COSV99589813; called by muse, mutect2, varscan2
- NRXN1 | c.3032C>T p.T1011M | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199980022, COSV100457555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD1 | c.4349C>T p.A1450V | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100729935; called by muse, mutect2, varscan2
- NSF | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs773404010, COSV56574478; called by muse, mutect2, varscan2
- NSUN6 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV101046064; called by muse, mutect2, varscan2
- NTRK2 | c.1009A>T p.T337S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.05); catalogued as COSV99459365; called by muse, mutect2, varscan2
- NTRK3 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV58118655, COSV58121837; called by muse, mutect2, varscan2
- NTRK3 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs1222179640, COSV58113091, COSV58150630; called by muse, mutect2, varscan2
- NXF1 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1179084923, COSV99585922; called by muse, mutect2, varscan2
- NXPE4 | c.1346G>A p.R449Q (on ENST00000375478 / NM_001077639.2; = p.R165Q on NM_017678.3) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as rs1018607965, COSV100970600; called by muse, mutect2
- NYAP1 | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs778518564, COSV55720246; called by muse, mutect2, varscan2
- OBSCN | c.12386A>G p.H4129R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99486112; called by muse, mutect2, varscan2
- OIT3 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs376142653; called by muse, mutect2, varscan2
- OPN1SW | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1160961990, COSV50821717, COSV99975986; called by muse, mutect2, varscan2
- OR1A1 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs148660594; called by muse, mutect2, varscan2
- OR1A2 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101126399; called by muse, mutect2, varscan2
- OR51B2 | c.17C>A p.T6N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.071); catalogued as COSV100173574; called by muse, mutect2, varscan2
- OR51E1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs758137608, COSV101211577; called by muse, mutect2, varscan2
- OR51Q1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs750405873, COSV56179937; called by muse, mutect2, varscan2
- OR52L1 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100176233; called by muse, mutect2, varscan2
- OR5K2 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.127); catalogued as COSV101415992; called by muse, mutect2, varscan2
- OR9Q2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs1455959865, COSV61111863, COSV61112062; called by muse, mutect2, varscan2
- OSBPL1A | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100112993; called by muse, mutect2, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 26/89 reads (29%) | catalogued as rs780916980; called by mutect2, varscan2
- OSBPL5 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as rs775147478, COSV99720920; called by muse, mutect2, varscan2
- OSBPL5 | c.1058A>C p.E353A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99720922; called by muse, mutect2, varscan2
- OTOF | c.4859G>A p.C1620Y (on ENST00000272371 / NM_194248.3; = p.C853Y on NM_004802.4) | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99719370; called by muse, mutect2, varscan2
- P2RX1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs368291814, COSV99844681, COSV99845036; called by muse, mutect2
- P2RY13 | c.702del p.V235Yfs*81 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs771457469; called by mutect2, pindel, varscan2
- PABPC1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs777648449, COSV100589947; called by muse, mutect2, varscan2
- PAG1 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757256493, COSV99598018; called by muse, mutect2, varscan2
- PARP6 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.707); catalogued as rs751254875, COSV99536470; called by muse, mutect2, varscan2
- PARPBP | c.349T>G p.L117V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as COSV100569347; called by muse, mutect2, varscan2
- PAX2 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1462521439, COSV100695507; called by muse, mutect2, varscan2
- PAX5 | c.76G>T p.V26F | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63906212; called by muse, mutect2, varscan2
- PC | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs745486772, COSV58993656; called by muse, mutect2, varscan2
- PCDHA1 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as COSV65374644; called by muse, mutect2, varscan2
- PCDHA11 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); catalogued as rs1554164932, COSV56530230; called by muse, mutect2
- PCDHA6 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.042); catalogued as rs1194699670, COSV101134309; called by muse, mutect2, varscan2
- PCDHA9 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100969348; called by muse, mutect2, varscan2
- PCDHB15 | c.712A>G p.N238D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99179321; called by muse, mutect2, varscan2
- PCDHGB7 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs753470433, COSV53915235; called by muse, mutect2, varscan2
- PCDHGC3 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1347278637, COSV99342949; called by muse, mutect2
- PCK2 | c.1295C>A p.P432H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99394735; called by muse, mutect2, varscan2
- PCNT | c.4864G>A p.A1622T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV100856186; called by muse, mutect2, varscan2
- PCNX2 | c.2800G>A p.V934I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs574508476, COSV99270049; called by muse, mutect2, varscan2
- PDE2A | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.312); catalogued as rs202076454, COSV100558536; called by muse, mutect2, varscan2
- PDGFRA | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.815); catalogued as COSV99958001; called by muse, mutect2, varscan2
- PDZRN3 | c.2230A>G p.T744A | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.338); catalogued as COSV99732846; called by muse, mutect2, varscan2
- PER3 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1403141361, COSV100728536; called by muse, mutect2
- PES1 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs202135025, COSV100073398; called by muse, mutect2, varscan2
- PFKL | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100827328; called by muse, mutect2
- PFKP | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs755208226, COSV66901131; called by muse, mutect2, varscan2
- PFN2 | c.151A>T p.I51F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV99526273; called by muse, mutect2, varscan2
- PGAP2 | c.232C>T p.R78C (on ENST00000463452 / NM_001346398.2; = p.R139C on NM_014489.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772273646, COSV53465232; called by muse, mutect2, varscan2
- PHLDB3 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs186752767; called by muse, mutect2, varscan2
- PIK3CD | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.947); catalogued as rs201362243, COSV100740627; called by muse, mutect2, varscan2
- PIK3R1 | c.1975T>C p.C659R (on ENST00000521381 / NM_181523.3; = p.C389R on NM_181504.4) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163210; called by muse, mutect2, varscan2
- PIK3R6 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766215631; called by muse, mutect2, varscan2
- PITPNM2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752872683, COSV54899347; called by mutect2, varscan2
- PKD1 | c.7175G>A p.R2392H | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs761828545, COSV51918009; called by muse, mutect2, varscan2
- PKP4 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs201152077, COSV67679055, COSV67679395; called by muse, mutect2, varscan2
- PLA2G12A | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs771775332, COSV99697317; called by muse, mutect2, varscan2
- PLAT | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99535514; called by muse, mutect2, varscan2
- PLCD1 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs760631515, COSV52186942; called by muse, mutect2, varscan2
- PLCL1 | c.2486G>A p.R829H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.411); catalogued as COSV70823668; called by muse, mutect2, varscan2
- PLEKHA8 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs755362074, COSV99322206, COSV99322414; called by muse, mutect2, varscan2
- PLEKHF1 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71410524; called by muse, mutect2, varscan2
- PLEKHG3 | c.2180C>T p.S727L (on ENST00000394691; = p.S783L on NM_001308147.2) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs1199237564, COSV99906667; called by muse, mutect2, varscan2
- PLIN3 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99701807; called by muse, mutect2, varscan2
- PLOD3 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as rs200112480, COSV56181304; called by muse, mutect2, varscan2
- PLRG1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57422822; called by muse, varscan2
- PLXDC1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100195936; called by muse, mutect2, varscan2
- PLXND1 | c.5110C>A p.L1704M | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100140583; called by muse, mutect2, varscan2
- PNPLA5 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs144693499, COSV53376278; called by muse, mutect2
- POC1B-GALNT4 | c.459_460del p.H153Qfs*19 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs1228425296; called by pindel, varscan2
- PODNL1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as rs1366737632, COSV54309105; called by muse, mutect2, varscan2
- POLD1 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 48/125 reads (38%) | catalogued as rs377690809; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- POLR1B | c.3268G>A p.A1090T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.253); catalogued as COSV54502813, COSV99638762; called by muse, mutect2, varscan2
- POLR2A | c.3856C>T p.R1286C | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1424901781; called by muse, mutect2, varscan2
- POP4 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs779780512, COSV55676044; called by muse, mutect2, varscan2
- POU2F1 | c.1380+1G>A p.X460_splice (on ENST00000541643 / NM_001365848.1; = p.X483_splice on NM_002697.4) | Splice Site (SNP) | VAF 15/32 reads (47%) | catalogued as COSV99612702; called by muse, mutect2, varscan2
- PPARG | c.572A>G p.Q191R (on ENST00000287820 / NM_015869.5; = p.Q161R on NM_005037.7) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV99826895; called by muse, mutect2, varscan2
- PPIL3 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as COSV99627035; called by mutect2, varscan2
- PPL | c.5027G>A p.R1676H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs751113704, COSV52174309; called by muse, mutect2, varscan2
- PPM1M | c.367C>T p.R123W (on ENST00000296487; = p.R284W on NM_144641.4) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs370443102, COSV56598986; called by muse, mutect2, varscan2
- PPP1CB | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); catalogued as COSV99942017; called by muse, mutect2, varscan2
- PPP1R14C | c.235A>T p.K79* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100745342; called by muse, mutect2, varscan2
- PRKX | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs149966538, COSV99468713, COSV99468798; called by muse, mutect2, varscan2
- PRLHR | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs201597278, COSV99493037; called by muse, mutect2, varscan2
- PRM2 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV99617833; called by muse, mutect2, varscan2
- PRMT3 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100424330; called by muse, mutect2, varscan2
- PRX | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99398167; called by muse, mutect2, varscan2
- PSG1 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.29); catalogued as rs201335145, COSV54947316; called by muse, mutect2, varscan2
- PSMB7 | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs749255446, COSV99413159; called by muse, mutect2, varscan2
- PTCHD1 | c.1126T>C p.S376P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV101038069; called by muse, mutect2, varscan2
- PTEN | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as CM004280, CM124222, COSV100909550, COSV64289957, COSV64297290; called by muse, mutect2, varscan2
- PTGER4 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs751806134, COSV100201798; called by muse, mutect2
- PTGFR | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV66115553, COSV66115721; called by muse, mutect2, varscan2
- PTPN14 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65284514; called by muse, varscan2
- PTPRD | c.5542G>A p.V1848I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745582718, COSV61979328; called by muse, mutect2, varscan2
- PTPRF | c.5633G>A p.R1878H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100741339; called by muse, mutect2, varscan2
- PTPRH | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs753627783, COSV54744697; called by muse, mutect2, varscan2
- PTPRK | c.3596G>T p.R1199M (on ENST00000368215 / NM_001291984.2; = p.R1200M on NM_002844.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100951726; called by muse, mutect2
- PTPRU | c.2634C>A p.D878E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV100113988; called by muse, mutect2, varscan2
- PTPRZ1 | c.5502+2T>C p.X1834_splice | Splice Site (SNP) | VAF 14/52 reads (27%) | catalogued as COSV101100950; called by muse, mutect2, varscan2
- PTTG1IP | c.168C>T p.S56= | Splice Region (SNP) | VAF 13/63 reads (21%) | catalogued as rs200693153; called by muse, mutect2, varscan2
- PYCR3 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs776301894, COSV99643323; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773249438, COSV52964786; called by muse, mutect2, varscan2
- RADIL | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as rs770544310, COSV101271652; called by muse, mutect2, varscan2
- RAI1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs764349627, COSV99885374; called by muse, mutect2, varscan2
- RAI1 | c.5557G>A p.V1853M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs371083418; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAMP1 | c.447G>T p.*149Yext*50 | Nonstop Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99615034; called by muse, mutect2, varscan2
- RAPGEF1 | c.2761C>T p.R921W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100940914; called by muse, mutect2, varscan2
- RARA | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54192452; called by muse, mutect2, varscan2
- RASAL2 | c.3343C>T p.R1115C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs773285861, COSV100862640, COSV62714405; called by muse, mutect2, varscan2
- RASGRP2 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs367847638; called by muse, mutect2, varscan2
- RBM15 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV100873535; called by muse, mutect2, varscan2
- RBM15B | c.2251C>T p.L751F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs782094588, COSV100082427; called by muse, mutect2, varscan2
- RBM19 | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); catalogued as rs1243883768, COSV99926991; called by muse, mutect2, varscan2
- RBM33 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.063); catalogued as rs902655495, COSV100265823; called by muse, mutect2, varscan2
- RBM44 | c.1079G>A p.R360H (on ENST00000611254; = p.R994H on NM_001080504.2) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100390250, COSV57630287; called by muse, mutect2, varscan2
- RBMXL1 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | catalogued as rs773118441, COSV99557253; called by muse, mutect2, varscan2
- RBMXL2 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV60980061, COSV60981927; called by muse, mutect2
- RCC1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs763928410, COSV100868223; called by muse, mutect2, varscan2
- RCC1L | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as rs999123205; called by muse, mutect2, varscan2
- RELN | c.3871C>T p.R1291* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100635133, COSV59021318; called by muse, mutect2, varscan2
- RENBP | c.298T>C p.F100L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100130186; called by muse, mutect2, varscan2
- RET | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.775); catalogued as rs80236571, CM941221, COSV60691814; ClinVar: risk factor; called by muse, mutect2, varscan2
- RGL3 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1275290518, COSV100805336; called by muse, mutect2, varscan2
- RIN3 | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539718901, COSV53650483; called by muse, mutect2
- RIOX1 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as rs1027344120, COSV100408085; called by muse, mutect2
- RIPK1 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs746209638, COSV99455053; called by muse, mutect2, varscan2
- RIPOR1 | c.464G>A p.R155H (on ENST00000379312 / NM_001193522.2; = p.R151H on NM_024519.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1270478112, COSV50290812; called by muse, mutect2
- RNASE6 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as COSV100485967; called by muse, mutect2, varscan2
- RNF113B | c.485C>G p.T162R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1421247800, COSV57435927, COSV99940453; called by muse, mutect2, varscan2
- RNF122 | c.468A>G p.*156Wext*31 | Nonstop Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as COSV99823235; called by muse, mutect2, varscan2
- RNF122 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56359112; called by muse, mutect2, varscan2
- RNF123 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs771578425, COSV59692896; called by muse, mutect2, varscan2
- RNF175 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs560692292, COSV56841108, COSV99924117; called by muse, mutect2, varscan2
- RNF208 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.858); catalogued as rs148710367, COSV100763199; called by mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROCK1 | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV67695278; called by muse, mutect2, varscan2
- RP9 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs770824356, COSV51806108; called by muse, mutect2, varscan2
- RPF2 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100923365; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL23A | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.537); catalogued as rs759848914, COSV52643766; called by muse, mutect2, varscan2
- RPS15 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | catalogued as COSV99245557; called by muse, mutect2, varscan2
- RPS5 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs1168189220, COSV52191056, COSV99545192; called by muse, mutect2, varscan2
- RSF1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100408120; called by muse, mutect2, varscan2
- RTN2 | c.236G>T p.R79M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV55592962; called by muse, mutect2, varscan2
- RUNX1T1 | c.1195G>A p.A399T (on ENST00000265814 / NM_001198628.1; = p.A372T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs377594753; called by muse, mutect2, varscan2
- RYR3 | c.9808C>T p.R3270C (on ENST00000389232; = p.R3271C on NM_001036.6) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200295482, COSV101211811, COSV101213130; called by muse, mutect2, varscan2
- RYR3 | c.13338C>A p.N4446K (on ENST00000389232; = p.N4447K on NM_001036.6) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.138); catalogued as rs1207059445, COSV101215179; called by muse, mutect2, varscan2
- SAGE1 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100188091, COSV61017517; called by muse, mutect2, varscan2
- SALL4 | c.3127C>T p.H1043Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99409967; called by muse, mutect2, varscan2
- SARDH | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.271); catalogued as rs773227673, COSV100061401; called by muse, mutect2, varscan2
- SART3 | c.2170G>A p.V724I (on ENST00000228284; = p.V706I on NM_014706.4) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1555204171, COSV57210576; called by muse, mutect2, varscan2
- SASH3 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100795315; called by muse, mutect2, varscan2
- SCAF4 | c.3044G>A p.R1015Q | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs769380757, COSV54255425; called by muse, mutect2, varscan2
- SCN5A | c.5755C>T p.R1919C (on ENST00000333535 / NM_198056.3; = p.R1918C on NM_000335.5) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs199473328, COSV100351290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1D | c.638C>T p.T213M (on ENST00000338555; = p.T377M on NM_001130413.4) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs143319964; called by muse, mutect2, varscan2
- SEC24C | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100227214; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SELENOP | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as rs774705650, COSV100736941; called by muse, mutect2, varscan2
- SEMA6A | c.1942G>A p.V648I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as rs778751794, COSV56714113; called by muse, mutect2, varscan2
- SENP1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV50311259; called by muse, mutect2, varscan2
- SEPTIN11 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV53582143; called by muse, mutect2, varscan2
- SEPTIN4 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as rs1046847407, COSV100422243, COSV57898803; called by muse, mutect2, varscan2
- SEPTIN4 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100400496; called by muse, mutect2, varscan2
- SEPTIN8 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769267005, COSV99736749; called by muse, mutect2, varscan2
- SETBP1 | c.1861A>G p.K621E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as COSV99955437; called by muse, mutect2, varscan2
- SF3B2 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs769074530, COSV100488721; called by muse, mutect2, varscan2
- SFT2D2 | c.318+1G>A p.X106_splice | Splice Site (SNP) | VAF 59/214 reads (28%) | catalogued as COSV99608293; called by muse, mutect2, varscan2
- SH3BP4 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs566330944, COSV100749373; called by muse, mutect2, varscan2
- SH3PXD2A | c.2399C>T p.S800L (on ENST00000369774 / NM_001365079.1; = p.S772L on NM_014631.2) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs564423308, COSV100279947; called by muse, mutect2, varscan2
- SHB | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1477599530, COSV100891937; called by muse, mutect2, varscan2
- SHC1 | c.1288G>A p.V430I (on ENST00000368445 / NM_183001.5; = p.V321I on NM_003029.5) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs1415630883, COSV63534534; called by muse, mutect2, varscan2
- SHLD2 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100079658; called by muse, mutect2, varscan2
- SHPRH | c.4396G>A p.V1466M (on ENST00000275233 / NM_001042683.3; = p.V1470M on NM_173082.3) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs764127816, COSV99262873; called by muse, mutect2, varscan2
- SHROOM3 | c.2434C>A p.H812N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99935672; called by muse, mutect2, varscan2
- SIGLEC1 | c.2243G>T p.G748V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99171511; called by muse, mutect2, varscan2
- SIGLEC1 | c.1118A>G p.H373R | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1269268655, COSV99171513; called by muse, mutect2, varscan2
- SIK3 | c.1786C>T p.Q596* (on ENST00000445177 / NM_001366686.2; = p.Q602* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV52618217; called by muse, mutect2, varscan2
- SIPA1L2 | c.3082G>A p.G1028S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.791); catalogued as rs778636218, COSV99479984; called by muse, mutect2, varscan2
- SKOR1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58244720; called by muse, mutect2, varscan2
- SLC15A2 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as rs145317059; called by muse, mutect2, varscan2
- SLC17A2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs764054503, COSV99615135; called by muse, mutect2, varscan2
- SLC18A3 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100341111; called by muse, mutect2, varscan2
- SLC22A4 | c.951G>T p.E317D | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV99569642; called by muse, mutect2
- SLC22A8 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371693018; called by muse, mutect2, varscan2
- SLC25A41 | c.100del p.Q34Nfs*44 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs745556777; called by mutect2, pindel, varscan2
- SLC25A6 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1229417562, COSV58431175; called by muse, mutect2, varscan2
- SLC35F2 | c.934T>C p.Y312H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99758952; called by muse, mutect2
- SLC3A1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs142482973; called by muse, mutect2, varscan2
- SLC45A4 | c.1579G>A p.V527M (on ENST00000517878 / NM_001286646.2; = p.V476M on NM_001080431.2) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs374269303; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs759883814, COSV56092392; called by pindel, varscan2
- SLC4A5 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs140446442; called by muse, mutect2, varscan2
- SLC5A1 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as COSV56688458; called by muse, mutect2, varscan2
- SLC5A4 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs541321389, COSV56669476; called by muse, mutect2, varscan2
- SLC7A3 | c.1613A>G p.H538R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.171); catalogued as COSV99979946; called by muse, mutect2, varscan2
- SLCO4A1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.322); catalogued as rs373121417; called by muse, mutect2, varscan2
- SMAD3 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs377026877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD3 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV59280523, COSV59280801; called by muse, mutect2, varscan2
- SMARCA4 | c.3626G>A p.S1209N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs145476154; ClinVar: uncertain significance; called by muse, mutect2
- SMARCC2 | c.3605C>T p.P1202L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs368771647, COSV99519510; called by muse, mutect2, varscan2
- SMC1A | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100447738; called by muse, mutect2, varscan2
- SMC5 | c.2234A>G p.Q745R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as COSV100747194; called by muse, mutect2, varscan2
- SOHLH2 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs368630913; called by muse, mutect2, varscan2
- SOS1 | c.1941-1G>T p.X647_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101217366; called by muse, mutect2, varscan2
- SOX4 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs781612610, COSV99782234; called by muse, mutect2, varscan2
- SOX6 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100323574; called by muse, mutect2, varscan2
- SPAG17 | c.2885A>C p.K962T | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100310993; called by muse, mutect2, varscan2
- SPAG9 | c.3737C>T p.T1246M (on ENST00000262013 / NM_001130528.3; = p.T1232M on NM_003971.6) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs200041587; called by muse, mutect2, varscan2
- SPAM1 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs943732895, COSV99773640; called by muse, varscan2
- SPINK9 | c.17T>C p.I6T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1262611055, COSV100930759; called by muse, mutect2, varscan2
- SPPL2B | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.46); catalogued as rs375894388; called by muse, mutect2, varscan2
- SPRY2 | c.880A>G p.K294E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV101001778; called by muse, mutect2, varscan2
- SPRYD7 | c.374A>C p.Q125P | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100709899; called by muse, mutect2, varscan2
- SPTBN5 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757739593, COSV100312439; called by muse, mutect2, varscan2
- SRGAP2 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.284); catalogued as rs782438952, COSV55341208; called by muse, mutect2, varscan2
- SSBP3 | c.664G>A p.G222S (on ENST00000371320 / NM_145716.4; = p.G202S on NM_018070.5) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs151118225; called by muse, mutect2, varscan2
- SSTR3 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1311437187, COSV100142941; called by muse, mutect2, varscan2
- STEAP2 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99840756; called by muse, mutect2, varscan2
- STEAP2 | c.1198T>C p.Y400H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.934); catalogued as COSV99840761; called by muse, mutect2, varscan2
- STK16 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as rs375565820; called by mutect2, varscan2
- STK39 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100597448; called by muse, mutect2, varscan2
- SUCO | c.3124G>T p.D1042Y | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99744058; called by muse, mutect2, varscan2
- SULF1 | c.1670T>A p.I557K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.9); catalogued as COSV99484667; called by muse, mutect2, varscan2
- SWT1 | c.1664A>G p.K555R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV100833589; called by muse, mutect2, varscan2
- SYBU | c.1556C>T p.A519V (on ENST00000276646 / NM_001099754.2; = p.A518V on NM_017786.6) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs372495769; called by muse, mutect2, varscan2
- SYN1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV99512330; called by muse, mutect2, varscan2
- SYNGR2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.603); catalogued as rs9889851, COSV99857400; called by muse, mutect2, varscan2
- SYT13 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs756301285, COSV99194652, COSV99194889; called by muse, mutect2, varscan2
- SZT2 | c.3665G>A p.R1222H (on ENST00000634258 / NM_001365999.1; = p.R1165H on NM_015284.4) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs368376076; called by muse, mutect2, varscan2
- TAAR5 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.434); catalogued as COSV99237029; called by muse, mutect2
- TAF1 | c.3281G>A p.S1094N (on ENST00000373790 / NM_138923.4; = p.S1115N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99337381; called by muse, mutect2, varscan2
524 further variants in this file (175 protein-altering or splice-affecting, 325 silent, 24 other) are not listed here.
